Surgical pathology report (de-identified scan), TCGA case TCGA-34-8454, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-8454-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:**Summary Statement**

The right lower lobectomy reveals a 4.8 cm, moderately differentiated squamous cell carcinoma with visceral pleural invasion associated with a 2.1 cm satellite metastasis, with involvement of N1 lymph nodes, occurring in the setting of severe emphysematous change with respiratory bronchiolitis and smoker's-associated interstitial fibrosis. Pathologic stage is T3 N1 (see comment).

PART 1: LYMPH NODE, LEVEL 9 LYMPH NODE, BIOPSY –

SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 2: LYMPH NODE, LEVEL 9 LYMPH NODE, BIOPSY –

SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 3: LYMPH NODE, LEVEL 10 LYMPH NODE, BIOPSY –

TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 4: LYMPH NODE, LEVEL 11 LYMPH NODE, BIOPSY –

THREE FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 5: LUNG, RIGHT LOWER LOBE, LOBECTOMY –

- A. INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 4.8 CM IN DIAMETER, WITH VISCERAL PLEURAL AND ANGIOLYMPHATIC INVASION, ASSOCIATED WITH A 2.1 CM INTRALOBAR SATELLITE METASTASIS. FINAL MARGINS FREE (see comment). MODERATE HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE: T3 N1.
- B. SEVERE EMPHYSEMATOUS CHANGE WITH RESPIRATORY BRONCHIOLITIS, INCLUDING EMPHYSEMATOUS BULLAE AND SMOKER'S ASSOCIATED INTERSTITIAL FIBROSIS.
- C. TWO OF THIRTEEN N1 LYMPH NODES POSITIVE FOR METASTATIC SQUAMOUS CELL CARCINOMA.
- D. ATYPICAL ADENOMATOUS HYPERPLASIA.
- E. PATCHY POST-OBSTRUCTIVE PNEUMONIA.

PART 6: LUNG, RIGHT UPPER LOBE, WEDGE BIOPSY –

- A. EXTENSIVE EMPHYSEMATOUS CHANGE WITH EMPHYSEMATOUS BULLAE, RESPIRATORY BRONCHIOLITIS, BRONCHIECTASIS, AND SMOKER'S ASSOCIATED INTERSTITIAL FIBROSIS.
- B. SMALL CARCINOID TUMORLET.
- C. FOCAL BRONCHIOLAR DYSPLASIA.

PART 7: LYMPH NODE, LEVEL 7 LYMPH NODE, BIOPSY -

TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 8: LYMPH NODE, LEVEL 4 LYMPH NODE, BIOPSY -

SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY LUNG TUMORS**

TUMOR LOCATION:	Right Lower Lobe
PROCEDURE:	Bilobectomy
TUMOR SIZE:	Maximum dimension: 4.8 cm Minor dimension: 4.0 cm
GROSS SATELLITES:	Number of gross satellite lesions: 1
TUMOR TYPE:	Invasive squamous carcinoma, peripheral type
HISTOLOGIC GRADE:	G2, Moderately differentiated
EXTRAPULMONARY EXTENSION/INVASION OF TUMOR:	Visceral pleura (PL2)
ANGIOLYMPHATIC INVASION:	Yes
TUMOR NECROSIS:	< or = to 50%
SURGICAL MARGIN INVOLVEMENT:	No
SURGICAL MARGIN SITE:	Distance of invasive tumor to closest margin: 15 mm, Bronchial margin
INFLAMMATORY(DESMOPLASTIC) REACTION:	Moderate
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 2 Number of N1 lymph nodes examined: 28
EXTRACAPSULAR SPREAD OF N1 METASTASES:	No
N1 LYMPH NODES INVOLVED:	Level 12
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 14
UNDERLYING DISEASE(S):	Emphysema, Smokers bronchiolitis
T STAGE, PATHOLOGIC:	pT3
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	Not applicable
ANCILLARY STUDIES:	Histochemical stains, FISH studies, Molecular studies
Comment:	PAS and PAS-d stains for mucin are negative. VVG stains help demonstrate visceral pleural invasion.

[page 2 of 2]
SPECIAL PROCEDURES:

In Situ Procedure

Interpretation

PROBE: *FGFR1*(Fibroblast Growth Factor Receptor 1)/8p11.1q11.1

***FGFR1* FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE POSITIVE FOR AMPLIFICATION.**

Number of cells analyzed: 61

Ratio *FGFR1*/Centromere8: 2.64

SNR (signal to nucleus ratio): 5.1

CNR (centromere to nucleus ratio): 1.9

Results

Description: *FGFR1*(Fibroblast Growth Factor Receptor 1) is a protein coding gene whose largest transcript features 18 exons, measures 5.6 kb and is located on chromosome 8p11.2. The *FGFR1* probe mix consists of a green 154kb probe telomeric to the *FGFR1* gene spanning the *LETM2-202* gene and D8S135 marker. The red probe is 52kb centromeric to the *FGFR1* gene spanning a 108kb region including the D8S389 marker.

FGFR1 FISH positive:

Gene Amplification: Ratio gene/chromosome more than two

FGFR1 FISH negative:

Ratio gene/chromosome less than two

f

Source: NCI Genomic Data Commons file cc4e00c1-bf2e-4bc4-be20-968da7addf4d (TCGA-34-8454.5A59CE20-3E53-4370-B09D-40D784C679E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).